Somatic mutation profile of tumor specimen TARGET-10-PASXUU-09A (aliquot TARGET-10-PASXUU-09A-01D) from TARGET case TARGET-10-PASXUU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,562 days).
Specimen TARGET-10-PASXUU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd2d70b0-f122-41f0-8300-fb5602c75b99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASXUU-10A (Blood Derived Normal), aliquot TARGET-10-PASXUU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90a2468f-964c-42f6-8ce3-a43b9beaeddd

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Splice Site 1, Intron 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP9A | c.3052G>T p.V1018F | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100125167, COSV58768733; called by muse, mutect2, varscan2
- FRMD5 | c.817T>G p.F273V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV68723593; called by muse, mutect2, varscan2
- MYO1E | c.760del p.E254Sfs*9 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as COSV55697294; called by mutect2, pindel, varscan2
- OR2B3 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV65851051; called by muse, mutect2, varscan2
- RNF182 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs141988852; called by muse, mutect2, varscan2
- MANSC4 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.598); called by muse, mutect2
- TPR | c.331-2_331-1insC p.X111_splice | Splice Site (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel*
- GDF9 | c.681C>T p.N227= | Silent (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- ICA1L | c.1048C>T p.L350= | Silent (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- PPT1 | c.288G>A p.Q96= (on ENST00000433473; = p.Q97= on NM_000310.4) | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV65655545; called by muse, mutect2, varscan2
- ABCB9 | c.1054-43C>G | Intron (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- GRIK1 | c.-4G>A | 5'UTR (SNP) | VAF 9/35 reads (26%) | catalogued as COSV58718389; called by muse, mutect2, varscan2
